Somatic mutation profile of tumor specimen TARGET-15-SJMPAL012422-09A.1 (aliquot TARGET-15-SJMPAL012422-09A.1-01D) from TARGET case TARGET-15-SJMPAL012422, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,552 days).
Specimen TARGET-15-SJMPAL012422-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a78bd901-229f-4bc6-b13c-2ad5411318ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL012422-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL012422-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8480aada-ed4b-484b-b2fd-d2a8c2019156

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, RNA 1, Frame Shift Ins 1, Nonsense Mutation 1, 3'UTR 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPD3 | c.374A>G p.Y125C (on ENST00000396553 / NM_001025389.2; = p.Y134C on NM_000480.3) | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.195); catalogued as rs781521325; called by muse, mutect2, varscan2
- RPS6KA6 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.18); catalogued as COSV53125495; called by muse, mutect2, varscan2
- ARHGAP42 | c.1129A>G p.T377A | Missense Mutation (SNP) | VAF 45/72 reads (63%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CD300LG | c.512C>A p.T171K | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- DIS3L2 | c.820_821insAGGCC p.R274Qfs*66 | Frame Shift Ins (INS) | VAF 56/154 reads (36%) | called by mutect2, pindel, varscan2
- EVX1 | c.53C>A p.T18N | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- HYDIN | c.4490A>T p.D1497V | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- KIF4B | c.302C>A p.A101E | Missense Mutation (SNP) | VAF 151/301 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- LCP2 | c.993G>T p.Q331H | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- NAP1L3 | c.932T>C p.I311T | Missense Mutation (SNP) | VAF 65/66 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SBNO2 | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- UBR2 | c.2646C>A p.C882* | Nonsense Mutation (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- FREM1 | c.2937G>A p.L979= | Silent (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- HAPLN1 | c.603G>T p.G201= | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2
- TTC6 | c.966T>C p.A322= (on ENST00000267368; = p.A1688= on NM_001310135.3) | Silent (SNP) | VAF 45/84 reads (54%) | called by muse, mutect2, varscan2
- CD3D | c.*28G>A | 3'UTR (SNP) | VAF 71/157 reads (45%) | called by muse, mutect2, varscan2
- IRF3 | c.165+228G>A | Intron (SNP) | VAF 43/97 reads (44%) | catalogued as rs763860251; called by muse, mutect2, varscan2
- RPAIN | c.-141C>A | 5'UTR (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- SMPD4BP | n.2562_2563del | RNA (DEL) | VAF 23/55 reads (42%) | called by mutect2, pindel*, varscan2*
